CCDI case PBCERI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d7b7ba74-4c85-4993-8733-673fa6d56fcc

Demographics
Sex at birth: male.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 2.2 years (812 days).

Biospecimens (3 samples)
- Sample 0DQU4U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DQU57: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRB5E: Tissue type: Tumor; Specimen type: Solid Tissue.
